Somatic mutation profile of tumor specimen TCGA-ZG-A8QX-01A (aliquot TCGA-ZG-A8QX-01A-11D-A377-08) from TCGA case TCGA-ZG-A8QX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.6 years (20,683 days).
Specimen TCGA-ZG-A8QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51afb1f3-f551-4e8d-bfc3-30cbd4ef570e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A8QX-10A (Blood Derived Normal), aliquot TCGA-ZG-A8QX-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6b90ce2-ff16-4089-85b2-b8e15b642ed9

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.1305+1G>A p.X435_splice | Splice Site (SNP) | VAF 13/40 reads (33%) | catalogued as rs758947077, COSV99054642; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPOP | c.259T>A p.Y87N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1057519972, COSV61652887, COSV61655982; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAG1 | c.566A>T p.K189I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99794660; called by muse, mutect2, varscan2
- DISC1 | c.2216A>G p.E739G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100790783; called by muse, mutect2
- DNAJC10 | c.1900A>G p.I634V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99899580; called by muse, mutect2
- FAF1 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100876082; called by muse, mutect2, varscan2
- HAPLN1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216047300, COSV99165175; called by muse, mutect2, varscan2
- HEPACAM2 | c.890C>T p.P297L (on ENST00000394468 / NM_001039372.4; = p.P285L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100506569; called by muse, mutect2, varscan2
- HOXC4 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324385; called by mutect2, varscan2
- IGHG1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745790229; called by muse, mutect2, varscan2
- LCP1 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100550062; called by muse, mutect2, varscan2
- MACROD2 | c.946C>T p.P316S (on ENST00000642719; = p.P288S on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs985251595, COSV54075180; called by muse, mutect2
- MEN1 | c.531T>A p.D177E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99581637; called by muse, mutect2, varscan2
- MYO18B | c.6529G>A p.A2177T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV100124992; called by muse, mutect2, varscan2
- NR4A2 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs774046320, COSV100277370; called by muse, mutect2, varscan2
- PCDHGA6 | c.2415G>T p.R805S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99546051; called by muse, mutect2, varscan2
- SIX3 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.902); catalogued as COSV99578547; called by muse, mutect2, varscan2
- SPAG16 | c.360G>C p.M120I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV99794002; called by muse, mutect2, varscan2
- TBC1D17 | c.1093A>C p.N365H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99680905; called by muse, mutect2, varscan2
- WDR70 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs780728685, COSV99460117; called by muse, mutect2, varscan2
- ZNF285 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.127); catalogued as COSV100450130; called by muse, mutect2, varscan2
- CASZ1 | c.134del p.E45Gfs*43 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- CLEC3A | c.354C>T p.D118= (on ENST00000651443; = p.D109= on NM_005752.6) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs370712626; called by muse, mutect2, varscan2
- DISC1 | c.2214C>T p.S738= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs565912178, COSV64107243; called by muse, mutect2
- MBD1 | c.930C>T p.P310= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1175351161, COSV99497138; called by muse, mutect2, varscan2
- NLRP4 | c.1230C>T p.D410= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100017060, COSV56718704; called by muse, mutect2, varscan2
- ODF2 | c.295C>T p.L99= (on ENST00000434106 / NM_153433.2; = p.L75= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100654957; called by muse, mutect2, varscan2
- PIP5K1C | c.876C>T p.A292= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs775398523, COSV100095996; called by muse, mutect2, varscan2
- RNF17 | c.255C>T p.R85= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99694313; called by mutect2, varscan2
- ZNF468 | c.747C>T p.G249= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99700795; called by muse, mutect2
- XIST | n.10042G>A | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as rs1441733217; called by muse, mutect2, varscan2
